CCDI case PBBTDD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/d6847fb9-1d80-43e4-b61b-ae41a7f046ca

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 11.4 years (4,160 days).

Biospecimens (3 samples)
- Sample 0DGB93: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DGB9O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGDW6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
